Gene-level copy-number profile of tumor specimen TCGA-91-6836-01A from TCGA case TCGA-91-6836, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.6 years (19,216 days).
Specimen TCGA-91-6836-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f5c2f87f-c4c6-4902-9cd4-9faf00760a33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6836-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0bb40e06-93bc-430c-83da-c1a0261f0682

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 786; copy number 2: 16,200; copy number 3: 19,358; copy number 4: 8,992; copy number 5: 7,616; copy number 6: 4,845; copy number 7: 214; copy number 8: 64; copy number 9: 605; copy number 10: 4; copy number 12: 29; copy number 13: 12; copy number 16: 705; copy number 17: 172; copy number 20: 206.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6836-01A-21D-1854-01): tumor purity 0.67, ploidy 3.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:71,096,952–71,783,383, 1 gene (within-gene range 0–2): THSD4.
- chr15:71,147,650–71,549,832, 5 genes: THSD4-AS1, HMGB1P6, AC064799.2, AC064799.1, AC108861.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,011 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–161,766,227, 849 genes, copy number 12–20 (broad region; genes not listed).
- chr5:58,198–38,945,596, 605 genes, copy number 9 (broad region; genes not listed).
- chr8:41,426,655–43,254,089, 58 genes, copy number 7: SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2.
- chr8:128,150,116–128,220,803, 2 genes, copy number 7: MIR1208, RN7SKP226.
- chr11:105,974,826–106,311,791, 11 genes, copy number 8: RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2.
- chr12:19,775,451–33,576,200, 257 genes, copy number 13–20 (broad region; genes not listed).
- chr12:131,596,857–132,610,582, 53 genes, copy number 8: AC140063.1, AC117500.5, AC117500.3, LINC02414, AC117500.6, AC117500.4, RNA5SP377, AC117500.1, RPS6P21, SFSWAP, AC117500.2, RNA5SP378, RNU6-1017P, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.10, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1.
- chr14:28,800,084–38,606,098, 172 genes, copy number 7–12 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 4 genes, copy number 10 (within-gene range 3–10): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
